Somatic mutation profile of tumor specimen 665f4f0f-130c-4b09-9762-cd0696 (aliquot 665f4f0f-130c-4b09-9762-cd0696_D6_1) from CPTAC case 11OV002, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC.
Specimen 665f4f0f-130c-4b09-9762-cd0696: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1c9879a5-646e-45be-9bf1-4c580179a01f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen af8fcd15-fda9-49e8-9e04-5ce523 (Blood Derived Normal), aliquot af8fcd15-fda9-49e8-9e04-5ce523_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/406b89e1-a37a-4a19-88e4-0b39e82b0b8e

The open-access MAF lists 157 somatic variants for this specimen: 106 protein-altering or splice-affecting, 30 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 80, Silent 30, Nonsense Mutation 8, Intron 7, Frame Shift Del 6, Splice Site 5, 3'UTR 4, Splice Region 4, 5'UTR 4, RNA 3, 5'Flank 2, In Frame Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1010G>T p.R337L | Missense Mutation (SNP) | VAF 43/95 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs121912664, CM012663, CM104660, COSV52665150, COSV52691988, COSV52828545; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AKR7A2 | c.928G>T p.G310W | Missense Mutation (SNP) | VAF 148/470 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52517133; called by muse, mutect2, varscan2
- ARHGAP17 | c.2342G>A p.G781E (on ENST00000289968 / NM_001006634.3; = p.G703E on NM_018054.6) | Missense Mutation (SNP) | VAF 30/204 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.009); catalogued as rs1333909885; called by muse, mutect2, varscan2
- C20orf194 | c.3152A>G p.K1051R | Missense Mutation (SNP) | VAF 155/467 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772670526; called by muse, mutect2, varscan2
- CACNA1H | c.756G>A p.W252* | Nonsense Mutation (SNP) | VAF 76/231 reads (33%) | catalogued as rs1555510083; called by muse, varscan2
- CCDC158 | c.931C>A p.Q311K | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV66357437; called by muse, mutect2, varscan2
- CHD8 | c.7181del p.K2394Rfs*36 (on ENST00000646647 / NM_001170629.2; = p.K2115Rfs*36 on NM_020920.4) | Frame Shift Del (DEL) | VAF 7/62 reads (11%) | catalogued as rs1306254828, COSV63036921; called by mutect2, pindel
- DNAH17 | c.7089G>A p.M2363I | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.083); catalogued as rs763784609; called by muse, mutect2, varscan2
- EML2 | c.1166G>A p.R389Q | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs757718402, COSV99840372; called by muse, mutect2, varscan2
- EVI5L | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1417075982, COSV54487296; called by muse, mutect2, varscan2
- FAT3 | c.6244C>G p.P2082A | Missense Mutation (SNP) | VAF 231/566 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53079037; called by muse, mutect2, varscan2
- FCHSD1 | c.1010C>T p.A337V | Missense Mutation (SNP) | VAF 49/193 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.292); catalogued as rs755611664; called by muse, mutect2, varscan2
- HECTD4 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1371579572; called by muse, mutect2, varscan2
- HRNR | c.5489C>T p.P1830L | Missense Mutation (SNP) | VAF 66/1980 reads (3%) | SIFT tolerated (0.3); PolyPhen benign (0.067); catalogued as rs1425336869; called by muse, mutect2
- IRF5 | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as rs367931039; called by muse, mutect2, varscan2
- ITGAE | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.543); catalogued as rs1335009363, COSV53990843; called by muse, mutect2, varscan2
- ITPR2 | c.5803G>T p.E1935* | Nonsense Mutation (SNP) | VAF 10/162 reads (6%) | catalogued as COSV67269217; called by muse, mutect2
- KRT8 | c.348C>G p.N116K | Missense Mutation (SNP) | VAF 114/401 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53178672; called by muse, mutect2, varscan2
- LRIT1 | c.1259A>G p.D420G | Missense Mutation (SNP) | VAF 95/385 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100927986; called by muse, mutect2, varscan2
- LYZ | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 64/253 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs147465274; called by muse, mutect2, varscan2
- MAP3K11 | c.1649G>A p.R550Q | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.056); catalogued as rs764566604; called by muse, mutect2, varscan2
- MYH14 | c.4971G>T p.K1657N | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.854); catalogued as COSV99222154; called by muse, mutect2, varscan2
- NACAD | c.107G>A p.G36E | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as rs1332968877; called by muse, mutect2, varscan2
- NDNF | c.293A>T p.D98V | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as COSV65634771; called by muse, mutect2, varscan2
- NDNF | c.292G>T p.D98Y | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as COSV65632535; called by muse, mutect2, varscan2
- OBSCN | c.17554C>T p.R5852W | Missense Mutation (SNP) | VAF 54/160 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745847180, COSV99483839; called by muse, mutect2
- PALLD | c.2831T>A p.L944H (on ENST00000505667 / NM_001166108.2; = p.L927H on NM_016081.4) | Missense Mutation (SNP) | VAF 16/298 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99823650; called by muse, mutect2
- PLA2G6 | c.916C>T p.R306W | Missense Mutation (SNP) | VAF 93/497 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.712); catalogued as rs1301929071, COSV59270148; called by muse, mutect2, varscan2
- PRPF40B | c.1610-3C>G | Splice Region (SNP) | VAF 66/216 reads (31%) | catalogued as rs996492514; called by muse, mutect2, varscan2
- PRR32 | c.461G>A p.G154D | Missense Mutation (SNP) | VAF 120/267 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs1473554470, COSV64420950; called by muse, mutect2, varscan2
- RAB4B | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 67/217 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.049); catalogued as rs747898878; called by muse, mutect2, varscan2
- SH2B1 | c.2066C>T p.P689L | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs1235077749; called by muse, mutect2, varscan2
- SRPX | c.1043C>A p.P348H | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs771104950; called by muse, mutect2, varscan2
- TBX19 | c.309C>G p.Y103* | Nonsense Mutation (SNP) | VAF 101/328 reads (31%) | catalogued as COSV63196651; called by muse, mutect2, varscan2
- TEX14 | c.2050G>T p.D684Y (on ENST00000240361 / NM_001201457.2; = p.D678Y on NM_031272.5) | Missense Mutation (SNP) | VAF 75/303 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV53620295; called by muse, mutect2, varscan2
- TRIM42 | c.524A>G p.K175R | Missense Mutation (SNP) | VAF 104/608 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.134); catalogued as COSV99036494; called by muse, mutect2, varscan2
- TTC16 | c.338C>A p.S113* | Nonsense Mutation (SNP) | VAF 20/115 reads (17%) | catalogued as COSV58853198; called by muse, mutect2, varscan2
- USH2A | c.1421C>G p.P474R | Missense Mutation (SNP) | VAF 135/311 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as COSV100241510; called by muse, mutect2, varscan2
- ZKSCAN8 | c.1731C>A p.S577R | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV100362790; called by muse, mutect2
- AC093512.2 | c.*622-4C>G | Splice Region (SNP) | VAF 157/850 reads (18%) | called by muse, mutect2, varscan2
- ADAMTSL2 | c.1103G>T p.G368V | Missense Mutation (SNP) | VAF 153/516 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, mutect2
- AKR7A2 | c.929G>T p.G310V | Missense Mutation (SNP) | VAF 148/475 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ARHGAP44 | c.842A>T p.E281V | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATN1 | c.3540-5C>A | Splice Region (SNP) | VAF 52/245 reads (21%) | called by muse, mutect2, varscan2
- ATRX | c.4885A>T p.N1629Y | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BAG4 | c.1042_1060del p.Y348Tfs*44 | Frame Shift Del (DEL) | VAF 63/174 reads (36%) | called by mutect2, pindel, varscan2
- C6orf141 | c.199G>T p.A67S | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- CDKL5 | c.1074A>C p.E358D | Missense Mutation (SNP) | VAF 24/372 reads (6%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.006); called by muse, mutect2
- CFAP92 | c.1437C>G p.H479Q | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CHD8 | c.4498A>G p.I1500V (on ENST00000646647 / NM_001170629.2; = p.I1221V on NM_020920.4) | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- CLCA1 | c.2710A>G p.K904E | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- CNNM3 | c.140_166del p.G47_R55del | In Frame Del (DEL) | VAF 8/16 reads (50%) | called by mutect2, varscan2
- DNAJB12 | c.295G>C p.D99H (on ENST00000338820; = p.D65H on NM_017626.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- DNAJC13 | c.1350-2A>T p.X450_splice | Splice Site (SNP) | VAF 23/57 reads (40%) | called by muse, mutect2, varscan2
- DOC2A | c.722A>T p.Q241L | Missense Mutation (SNP) | VAF 138/560 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- DTHD1 | c.1847C>A p.T616N (on ENST00000456874; = p.T451N on NM_001136536.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, varscan2
- ELAVL3 | c.1075T>C p.F359L | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- EXTL1 | c.151G>T p.D51Y | Missense Mutation (SNP) | VAF 101/300 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FAM71D | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAR1 | c.1138del p.T380Qfs*2 | Frame Shift Del (DEL) | VAF 13/66 reads (20%) | called by mutect2, pindel, varscan2
- FCGBP | c.10179C>A p.D3393E | Missense Mutation (SNP) | VAF 194/594 reads (33%) | SIFT tolerated (0.72); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- FER1L5 | c.2830T>A p.F944I (on ENST00000623019; = p.F951I on NM_001293083.2) | Missense Mutation (SNP) | VAF 49/181 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- FITM1 | c.541T>C p.Y181H | Missense Mutation (SNP) | VAF 114/429 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- FLI1 | c.167A>G p.E56G | Missense Mutation (SNP) | VAF 466/896 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- FRY | c.1404_1446del p.D468Efs*14 | Frame Shift Del (DEL) | VAF 114/300 reads (38%) | called by mutect2, pindel, varscan2
- FSTL4 | c.781A>T p.T261S | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GGA2 | c.787G>C p.E263Q | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- HIGD2B | c.39T>G p.F13L | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- IFNG | c.481G>A p.G161S | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- INTS4 | c.1669A>T p.T557S | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- KAT2B | c.1168G>A p.V390M | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- KMT2A | c.8381A>G p.Q2794R | Missense Mutation (SNP) | VAF 69/204 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- L3MBTL1 | c.952-13_967del p.X318_splice (on ENST00000418998 / NM_001377303.1; = p.X228_splice on NM_015478.7) | Splice Site (DEL) | VAF 39/136 reads (29%) | called by mutect2, pindel, varscan2
- MKNK1 | c.1206G>T p.Q402H | Missense Mutation (SNP) | VAF 144/489 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- MYH13 | c.4661C>A p.S1554Y | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- MYO18B | c.2211G>T p.Q737H | Missense Mutation (SNP) | VAF 50/204 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NLRX1 | c.2739C>G p.I913M | Missense Mutation (SNP) | VAF 88/337 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NQO2 | c.7+2_7+47del p.X3_splice | Splice Site (DEL) | VAF 29/133 reads (22%) | called by mutect2, pindel, varscan2
- OR4Q2 | c.475G>C p.V159L | Missense Mutation (SNP) | VAF 109/476 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- OR6C3 | c.284C>A p.A95E | Missense Mutation (SNP) | VAF 54/250 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- OTUB1 | c.607T>G p.F203V | Missense Mutation (SNP) | VAF 73/228 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- PRPSAP1 | c.921T>A p.Y307* | Nonsense Mutation (SNP) | VAF 18/56 reads (32%) | called by muse, mutect2, varscan2
- PRR29 | c.292A>T p.M98L | Missense Mutation (SNP) | VAF 149/450 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- RETSAT | c.1536G>T p.V512= | Splice Region (SNP) | VAF 58/209 reads (28%) | called by muse, mutect2, varscan2
- RPRD2 | c.3798_3835del p.F1267* | Frame Shift Del (DEL) | VAF 88/281 reads (31%) | called by mutect2, pindel, varscan2
- RPS6KA3 | c.1739dup p.Y580* | Nonsense Mutation (INS) | VAF 82/219 reads (37%) | called by mutect2, pindel, varscan2
- SHROOM4 | c.2672_2704del p.S891_C901del | In Frame Del (DEL) | VAF 162/399 reads (41%) | called by mutect2, pindel, varscan2
- SIGLEC5 | c.890G>C p.G297A | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- SLC39A5 | c.496G>A p.V166I | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- SPARC | c.625G>T p.G209* | Nonsense Mutation (SNP) | VAF 67/219 reads (31%) | called by muse, mutect2, varscan2
- SPATA16 | c.500G>A p.S167N | Missense Mutation (SNP) | VAF 213/654 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.006); called by muse, mutect2
- SPTA1 | c.3635G>A p.G1212D | Missense Mutation (SNP) | VAF 173/596 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SVEP1 | c.7472C>G p.P2491R | Missense Mutation (SNP) | VAF 87/190 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TG | c.1951G>T p.V651F | Missense Mutation (SNP) | VAF 57/285 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- TGM3 | c.8-1G>A p.X3_splice | Splice Site (SNP) | VAF 34/128 reads (27%) | called by mutect2, varscan2
- TNC | c.5731dup p.R1911Pfs*12 | Frame Shift Ins (INS) | VAF 22/96 reads (23%) | called by mutect2, varscan2
- TTN | c.23698T>A p.C7900S (on ENST00000591111; = p.C6973S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 105/364 reads (29%) | PolyPhen benign (0.022); called by muse, mutect2, varscan2
- TTN | c.10174_10192del p.M3392Lfs*25 (on ENST00000591111; = p.M3346Lfs*25 on NM_003319.4) | Frame Shift Del (DEL) | VAF 53/388 reads (14%) | called by mutect2, pindel, varscan2
- TUBGCP5 | c.614G>A p.S205N | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- UBXN1 | c.27T>A p.S9R | Missense Mutation (SNP) | VAF 38/208 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- USP32 | c.38A>T p.Y13F | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WDR81 | c.3514C>T p.Q1172* (on ENST00000409644 / NM_001163809.2; = p.Q121* on NM_152348.4) | Nonsense Mutation (SNP) | VAF 60/127 reads (47%) | called by muse, mutect2, varscan2
- ZBED4 | c.61A>G p.K21E | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); called by muse, mutect2
- ZNF469 | c.1897G>C p.A633P | Missense Mutation (SNP) | VAF 75/209 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- ZNF492 | c.925T>C p.Y309H | Missense Mutation (SNP) | VAF 39/218 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- ZNFX1 | c.3216+2T>A p.X1072_splice | Splice Site (SNP) | VAF 35/102 reads (34%) | called by muse, mutect2, varscan2
- ANKRD55 | c.1119G>A p.E373= | Silent (SNP) | VAF 38/108 reads (35%) | called by muse, varscan2
- ARHGAP22 | c.1233G>A p.G411= | Silent (SNP) | VAF 105/265 reads (40%) | called by muse, mutect2, varscan2
- CACNA1C | c.6024C>A p.P2008= (on ENST00000399634 / NM_001167625.1; = p.P1937= on NM_000719.7) | Silent (SNP) | VAF 110/346 reads (32%) | called by muse, mutect2, varscan2
- CCDC130 | c.384G>A p.E128= | Silent (SNP) | VAF 41/146 reads (28%) | catalogued as rs762717175; called by muse, mutect2, varscan2
- CYRIA | c.498C>T p.R166= | Silent (SNP) | VAF 41/127 reads (32%) | called by muse, mutect2, varscan2
- DUOX2 | c.3024C>G p.P1008= | Silent (SNP) | VAF 96/212 reads (45%) | called by muse, mutect2, varscan2
- GALNT2 | c.726G>T p.A242= | Silent (SNP) | VAF 43/138 reads (31%) | catalogued as COSV100795819; called by muse, mutect2, varscan2
- IFT172 | c.930G>T p.V310= | Silent (SNP) | VAF 55/262 reads (21%) | called by muse, mutect2, varscan2
- LIPT2 | c.456C>A p.I152= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as rs947036591; called by muse, mutect2, varscan2
- MAP3K4 | c.3216G>A p.K1072= | Silent (SNP) | VAF 22/212 reads (10%) | called by muse, mutect2
- MEFV | c.603C>A p.V201= | Silent (SNP) | VAF 53/144 reads (37%) | called by muse, mutect2, varscan2
- OAF | c.591G>A p.E197= | Silent (SNP) | VAF 120/405 reads (30%) | called by muse, mutect2, varscan2
- OR4K5 | c.865C>T p.L289= | Silent (SNP) | VAF 17/334 reads (5%) | catalogued as rs1225573901; called by muse, mutect2
- PCDHGB4 | c.771G>C p.P257= | Silent (SNP) | VAF 64/298 reads (21%) | catalogued as rs375260597; called by muse, mutect2, varscan2
- PKP3 | c.1605C>T p.S535= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as rs764081999; called by muse, mutect2, varscan2
- PRDM16 | c.1206C>G p.S402= | Silent (SNP) | VAF 30/119 reads (25%) | called by muse, mutect2, varscan2
- PRDM6 | c.816C>A p.T272= | Silent (SNP) | VAF 66/228 reads (29%) | called by muse, mutect2, varscan2
- PRSS38 | c.456C>T p.A152= | Silent (SNP) | VAF 101/337 reads (30%) | called by muse, mutect2, varscan2
- RYR1 | c.4209C>G p.A1403= | Silent (SNP) | VAF 127/426 reads (30%) | called by muse, mutect2, varscan2
- STXBP1 | c.1482T>A p.L494= | Silent (SNP) | VAF 133/443 reads (30%) | called by muse, mutect2, varscan2
- TEX14 | c.549G>A p.V183= | Silent (SNP) | VAF 60/114 reads (53%) | called by muse, varscan2
- TMC5 | c.1071T>G p.L357= (on ENST00000396229 / NM_001105248.1; = p.L111= on NM_024780.5) | Silent (SNP) | VAF 12/39 reads (31%) | called by muse, mutect2, varscan2
- TRIM10 | c.1293G>A p.V431= | Silent (SNP) | VAF 109/400 reads (27%) | called by muse, mutect2, varscan2
- TSPAN15 | c.294C>T p.I98= | Silent (SNP) | VAF 71/188 reads (38%) | called by muse, mutect2, varscan2
- TTN | c.10638T>G p.S3546= (on ENST00000591111; = p.S3500= on NM_003319.4) | Silent (SNP) | VAF 110/656 reads (17%) | called by muse, mutect2, varscan2
- TXNDC5 | c.336C>G p.A112= | Silent (SNP) | VAF 43/280 reads (15%) | catalogued as COSV101124310; called by muse, mutect2, varscan2
- UNC13D | c.519G>A p.T173= | Silent (SNP) | VAF 106/351 reads (30%) | catalogued as rs370278536; ClinVar: likely benign; called by muse, mutect2, varscan2
- UNC93A | c.243C>T p.F81= | Silent (SNP) | VAF 25/178 reads (14%) | called by muse, mutect2, varscan2
- VAX2 | c.783C>G p.G261= | Silent (SNP) | VAF 26/85 reads (31%) | called by muse, mutect2, varscan2
- ZCCHC2 | c.3321C>T p.F1107= | Silent (SNP) | VAF 133/311 reads (43%) | catalogued as COSV54036063; called by muse, mutect2, varscan2
- BRD2 | c.-799G>T | 5'UTR (SNP) | VAF 20/61 reads (33%) | catalogued as rs1483560503; called by muse, mutect2, varscan2
- CCDC34 | c.*2G>T | 3'UTR (SNP) | VAF 14/36 reads (39%) | called by muse, mutect2, varscan2
- CENPJ | c.-39C>G | 5'UTR (SNP) | VAF 16/92 reads (17%) | called by muse, mutect2, varscan2
- CFAP74 | c.*21C>T | 3'UTR (SNP) | VAF 18/64 reads (28%) | catalogued as rs543489031; called by muse, mutect2, varscan2
- CSF3R | c.*14T>C | 3'UTR (SNP) | VAF 69/285 reads (24%) | called by muse, mutect2, varscan2
- EBNA1BP2 | chr1:43172413 T>A | 5'Flank (SNP) | VAF 55/142 reads (39%) | called by muse, mutect2, varscan2
- ERBB3 | c.*50T>G | 3'UTR (SNP) | VAF 37/111 reads (33%) | called by muse, mutect2, varscan2
- ERCC2 | c.1307+16G>A | Intron (SNP) | VAF 87/417 reads (21%) | called by muse, mutect2, varscan2
- GRHL3 | c.1694+4341T>C | Intron (SNP) | VAF 36/124 reads (29%) | called by muse, mutect2
- KATNIP | c.540+5882_540+5898del | Intron (DEL) | VAF 58/161 reads (36%) | called by mutect2, pindel, varscan2
- LINC00174 | n.3697C>A | RNA (SNP) | VAF 35/123 reads (28%) | called by muse, mutect2, varscan2
- MIR34AHG | n.1941G>C | RNA (SNP) | VAF 178/543 reads (33%) | called by muse, mutect2, varscan2
- PRICKLE2 | c.769-34T>A | Intron (SNP) | VAF 112/320 reads (35%) | called by mutect2, varscan2
- PRR14L | chr22:31676821 G>C | 3'Flank (SNP) | VAF 40/178 reads (22%) | catalogued as rs906518770; called by muse, mutect2, varscan2
- RFK | c.-4C>T | 5'UTR (SNP) | VAF 55/180 reads (31%) | called by muse, mutect2, varscan2
- SCART1 | c.2276-10T>C | Intron (SNP) | VAF 39/359 reads (11%) | called by muse, mutect2, varscan2
- SERPINA13P | n.1003T>G | RNA (SNP) | VAF 114/456 reads (25%) | called by muse, mutect2, varscan2
- SMARCAD1 | c.190+4554C>A | Intron (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- ZFP36 | c.-11C>G | 5'UTR (SNP) | VAF 17/50 reads (34%) | catalogued as COSV50527818; called by muse, mutect2, varscan2
- ZMYM6 | c.2147-1325G>C | Intron (SNP) | VAF 7/34 reads (21%) | catalogued as rs1020087265; called by muse, mutect2, varscan2
- ZNF598 | chr16:2009978 G>A | 5'Flank (SNP) | VAF 35/97 reads (36%) | called by muse, mutect2, varscan2
